Somatic mutation profile of tumor specimen TCGA-GV-A3QF-01A (aliquot TCGA-GV-A3QF-01A-31D-A22Z-08) from TCGA case TCGA-GV-A3QF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.1 years (28,890 days).
Specimen TCGA-GV-A3QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4737787f-93ae-4ac1-9bf7-f03fa4384139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3QF-10A (Blood Derived Normal), aliquot TCGA-GV-A3QF-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c09813c8-f8ce-4201-9b25-5b721f52e946

The open-access MAF lists 142 somatic variants for this specimen: 106 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 34, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 3, Intron 1, Translation Start Site 1, In Frame Del 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 28/42 reads (67%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- KIF1A | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs749718096, COSV100239902, COSV57482702; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59206538, COSV59210925; called by muse, mutect2, varscan2
- ABCD2 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58049521, COSV58055009, COSV58055073; called by muse, mutect2, varscan2
- ADCY1 | c.2328-1G>A p.X776_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV52030077; called by muse, mutect2, varscan2
- ANK2 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52146177; called by muse, mutect2, varscan2
- ANKRD35 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV62909538; called by muse, mutect2, varscan2
- AP3D1 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61424502; called by muse, mutect2, varscan2
- ARHGEF7 | c.1499A>C p.Y500S (on ENST00000375741 / NM_001113511.2; = p.Y322S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54538821; called by muse, mutect2, varscan2
- ATP1A4 | c.2586G>C p.Q862H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV63625440; called by muse, mutect2, varscan2
- BUD13 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52766963; called by muse, mutect2, varscan2
- BUD13 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52766978; called by muse, mutect2, varscan2
- CCDC42 | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1347827804, COSV53448022; called by muse, mutect2, varscan2
- CCHCR1 | c.2340G>A p.M780I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs370915688, COSV99455996; called by muse, mutect2, varscan2
- CDH4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs142330895; called by muse, mutect2, varscan2
- CFHR5 | c.1128T>A p.N376K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV56818017, COSV99889619; called by muse, mutect2, varscan2
- CNGA3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV55622124; called by muse, mutect2, varscan2
- CNTN3 | c.1006T>C p.Y336H | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55163196; called by muse, mutect2, varscan2
- CPNE1 | c.802G>A p.V268I (on ENST00000352393; = p.V273I on NM_003915.5) | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58289859; called by muse, mutect2, varscan2
- CPTP | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs752206526; called by muse, mutect2
- DHX36 | c.1271A>G p.Q424R | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV57670906; called by muse, mutect2, varscan2
- DNAH10 | c.817C>G p.Q273E (on ENST00000409039; = p.Q212E on NM_207437.3) | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV68987859; called by muse, mutect2, varscan2
- DNAH3 | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54503412; called by muse, mutect2, varscan2
- DNAH6 | c.1449G>C p.W483C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV52849839; called by muse, mutect2, varscan2
- ETV1 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54136760, COSV54140570; called by muse, mutect2, varscan2
- EVX1 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56084757; called by muse, mutect2, varscan2
- FER1L6 | c.3046C>G p.Q1016E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV67548138; called by muse, mutect2, varscan2
- FGA | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV57393119, COSV57394870; called by muse, mutect2
- FPGT-TNNI3K | c.973G>C p.G325R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV58545789, COSV58546216; called by muse, mutect2, varscan2
- GATAD2A | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.176); catalogued as rs1376397007, COSV53066374, COSV53070500; called by muse, mutect2, varscan2
- GPR89B | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.72); catalogued as COSV58501362; called by muse, mutect2, varscan2
- GRIK3 | c.2230G>T p.E744* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV66148127; called by muse, mutect2, varscan2
- GUCY1A1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs769362284, COSV56649134; called by muse, mutect2, varscan2
- H2AC20 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.362); catalogued as COSV100480000, COSV58611285; called by muse, mutect2, varscan2
- HMCN1 | c.5346G>C p.K1782N | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV54876220, COSV54877164; called by muse, mutect2, varscan2
- HMGB2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as COSV56633159; called by muse, mutect2, varscan2
- HSPA6 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59059917; called by muse, mutect2, varscan2
- IFT57 | c.1280G>C p.G427A | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV52708140, COSV99197340; called by muse, mutect2, varscan2
- IGSF10 | c.5182C>G p.L1728V | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56781565; called by muse, mutect2, varscan2
- IHH | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55392705; called by muse, mutect2, varscan2
- IL5RA | c.503A>C p.Q168P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56520988; called by muse, mutect2, varscan2
- ITGB2 | c.2204G>A p.G735D (on ENST00000302347; = p.G711D on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV56607714; called by muse, mutect2, varscan2
- IZUMO1 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV55802299, COSV55805346; called by muse, mutect2, varscan2
- LRRFIP2 | c.1752T>G p.I584M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60866209; called by muse, mutect2, varscan2
- MAGEA10 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV54882846, COSV54885313; called by muse, mutect2, varscan2
- MPEG1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57088242; called by muse, mutect2, varscan2
- MST1R | c.2995C>A p.L999M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV56564477; called by muse, mutect2, varscan2
- MYBPHL | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs763912500, COSV64062148; called by muse, mutect2, varscan2
- NPR3 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54084362; called by muse, mutect2, varscan2
- NUBPL | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV55264867, COSV99808918; called by muse, mutect2, varscan2
- OR2G6 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs370636108, COSV58575739; called by muse, mutect2, varscan2
- OR2T12 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV58776078; called by muse, mutect2, varscan2
- OR4P4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV58920597; called by muse, mutect2
- OSBPL10 | c.211del p.R71Afs*39 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as COSV100824471; called by mutect2, pindel, varscan2
- PDE11A | c.2398A>C p.I800L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53686298; called by muse, mutect2, varscan2
- PLCD1 | c.1694T>A p.V565E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52182421; called by mutect2, varscan2
- PRAMEF12 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.584); catalogued as COSV63214694; called by muse, mutect2, varscan2
- PRRT3 | c.1814C>G p.S605W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55976335; called by muse, mutect2, varscan2
- PTPN3 | c.2176_2188del p.A726Rfs*14 | Frame Shift Del (DEL) | VAF 27/52 reads (52%) | catalogued as COSV52701995; called by mutect2, pindel, varscan2
- PYGM | c.1645T>C p.Y549H | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV51214842; called by muse, mutect2, varscan2
- RLF | c.3940C>A p.H1314N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV65650627; called by muse, mutect2, varscan2
- RPL5 | c.190-1G>A p.X64_splice | Splice Site (SNP) | VAF 72/157 reads (46%) | catalogued as COSV59872867; called by muse, mutect2, varscan2
- SCN1A | c.3575G>T p.C1192F (on ENST00000303395 / NM_001202435.3; = p.C1181F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57660086; called by muse, mutect2, varscan2
- SLC34A2 | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV65940643; called by muse, mutect2, varscan2
- SMARCAL1 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61919866; called by mutect2, varscan2
- SMYD4 | c.1764G>T p.K588N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as COSV59710531; called by muse, mutect2, varscan2
- STOML1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774464130, COSV57550989; called by muse, mutect2, varscan2
- TANC1 | c.3266G>A p.R1089K | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV55083085; called by muse, mutect2, varscan2
- TFAP2A | c.221C>T p.P74L (on ENST00000482890; = p.P66L on NM_001032280.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60230863, COSV60230983; called by muse, mutect2, varscan2
- TLR9 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62345467; called by muse, mutect2, varscan2
- TMPRSS11B | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV60291226; called by muse, mutect2
- TNS1 | c.1558T>C p.S520P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50690603; called by muse, mutect2
- TP63 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 67/205 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV53196409, COSV53217837; called by muse, mutect2, varscan2
- TPBG | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs866426863, COSV63882240; called by muse, mutect2, varscan2
- TRAK1 | c.1640T>C p.L547P (on ENST00000327628 / NM_001349247.2; = p.L489P on NM_014965.5) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV58255559; called by muse, mutect2, varscan2
- TRAPPC12 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368315810, COSV60849998; called by muse, mutect2, varscan2
- TRERF1 | c.3024G>T p.Q1008H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61667131; called by mutect2, varscan2
- TSC1 | c.2392-1G>T p.X798_splice | Splice Site (SNP) | VAF 69/113 reads (61%) | catalogued as COSV53763695, COSV53765120; called by muse, mutect2, varscan2
- TTC9B | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.166); catalogued as COSV53420411; called by muse, mutect2, varscan2
- TTI1 | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs756784886, COSV65060450; called by muse, mutect2, varscan2
- TTN | c.27239C>A p.P9080H (on ENST00000591111; = p.P8153H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV59888049; called by muse, mutect2
- UBR4 | c.7758C>A p.N2586K | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV64382850; called by muse, mutect2, varscan2
- WAPL | c.1040G>T p.S347I | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); catalogued as COSV53932356; called by muse, mutect2, varscan2
- WDPCP | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55413066; called by muse, mutect2, varscan2
- WHRN | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV54326954; called by muse, mutect2, varscan2
- WWOX | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as rs369055872; ClinVar: uncertain significance; called by mutect2, varscan2
- ZBTB37 | c.111T>G p.N37K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV62931414; called by muse, mutect2, varscan2
- ZFHX4 | c.8077C>T p.H2693Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50494539; called by muse, mutect2, varscan2
- ZMIZ2 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV54806000; called by muse, mutect2, varscan2
- ZNF385D | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV55746309; called by muse, mutect2, varscan2
- ZNF536 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62818509, COSV62823576; called by muse, mutect2, varscan2
- ZP4 | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV63910911; called by muse, mutect2, varscan2
- CNOT1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 126/302 reads (42%) | called by muse, mutect2, varscan2
- EBF2 | c.1306del p.V436Sfs*44 | Frame Shift Del (DEL) | VAF 47/121 reads (39%) | called by mutect2, pindel, varscan2
- HES1 | c.180_182del p.I61del | In Frame Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- NME8 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- PDIA3 | c.507del p.E170Sfs*3 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.2476dup p.I826Nfs*7 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, varscan2
- PLD1 | c.1792del p.H598Mfs*3 | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | called by mutect2, pindel, varscan2
- RASGRP2 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- RLN1 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- SYT1 | c.1092_1093insAAC p.D364_Y365insN | In Frame Ins (INS) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.3671T>A p.L1224* (on ENST00000591111; = p.L1178* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2
- ZFP36L1 | c.593dup p.Q199Pfs*3 | Frame Shift Ins (INS) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.389dup p.S131Qfs*343 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ZNF574 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- ANKRD44 | c.1710A>T p.P570= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV56549446; called by muse, mutect2, varscan2
- ARID3C | c.915A>G p.A305= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as rs1158097139, COSV52406342; called by muse, mutect2, varscan2
- BDP1 | c.726A>G p.P242= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV62428933; called by muse, mutect2, varscan2
- BRIP1 | c.2112A>G p.L704= | Silent (SNP) | VAF 72/188 reads (38%) | catalogued as COSV51994068; called by muse, mutect2, varscan2
- CCDC170 | c.1206G>A p.E402= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53336623; called by muse, mutect2
- CCN3 | c.33C>T p.L11= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52383058; called by muse, mutect2, varscan2
- DNAH10 | c.7902G>A p.K2634= (on ENST00000409039; = p.K2573= on NM_207437.3) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV68987862, COSV99072552; called by muse, varscan2
- DOCK8 | c.4515C>T p.F1505= | Silent (SNP) | VAF 63/83 reads (76%) | catalogued as rs781102523, COSV66617620; called by muse, mutect2, varscan2
- DYSF | c.5295G>A p.V1765= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV50268079; called by muse, mutect2, varscan2
- FBN3 | c.5361C>T p.Y1787= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV54453398; called by muse, mutect2, varscan2
- GALR1 | c.864C>T p.A288= | Silent (SNP) | VAF 50/79 reads (63%) | catalogued as rs754119122, COSV55315861; called by muse, mutect2, varscan2
- GPR173 | c.450G>A p.L150= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV60233542; called by muse, mutect2, varscan2
- ITPRID1 | c.2190C>T p.P730= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV60070122; called by muse, mutect2, varscan2
- KSR2 | c.2457G>A p.E819= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1489478987, COSV56665757; called by muse, mutect2
- MAP2 | c.2553T>C p.T851= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV52281243; called by muse, mutect2, varscan2
- OR4M1 | c.696T>A p.G232= | Silent (SNP) | VAF 63/238 reads (26%) | catalogued as COSV60059424; called by muse, mutect2, varscan2
- OR51M1 | c.201G>T p.L67= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV60783780, COSV60783954; called by muse, mutect2, varscan2
- OR5W2 | c.387C>A p.P129= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV60614626; called by muse, mutect2, varscan2
- PCNX3 | c.2967T>C p.C989= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV63134747; called by muse, mutect2, varscan2
- PGC | c.288C>T p.N96= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV63122171; called by muse, mutect2, varscan2
- PIK3CB | c.243A>G p.A81= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs754142331, COSV56683381; called by muse, mutect2, varscan2
- PKHD1L1 | c.2853C>T p.P951= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs771022142, COSV65737090, COSV65756212; called by muse, mutect2, varscan2
- PTPN2 | c.1194T>A p.I398= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV58995264; called by muse, mutect2, varscan2
- PXDN | c.2604G>A p.R868= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV53226986; called by muse, mutect2, varscan2
- RBFOX1 | c.531C>T p.H177= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs1193035983, COSV60945876; called by muse, mutect2, varscan2
- SHCBP1 | c.978C>A p.S326= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV57646341; called by muse, mutect2, varscan2
- SLC39A12 | c.1899C>A p.I633= (on ENST00000377369 / NM_001145195.2; = p.I596= on NM_152725.3) | Silent (SNP) | VAF 102/220 reads (46%) | catalogued as rs1479768480, COSV66195027; called by muse, mutect2, varscan2
- TBC1D8 | c.453C>T p.F151= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs897230514, COSV65209753; called by muse, mutect2, varscan2
- TMEM204 | c.51A>G p.S17= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs1159848028, COSV54151558; called by muse, mutect2
- TRHR | c.876C>T p.L292= | Silent (SNP) | VAF 120/330 reads (36%) | catalogued as rs867428496, COSV61232824; called by muse, mutect2, varscan2
- TTN | c.3669C>A p.A1223= (on ENST00000591111; = p.A1177= on NM_003319.4) | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV59888094; called by muse, mutect2
- WDR7 | c.4320G>A p.Q1440= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV54348177; called by muse, mutect2, varscan2
- ZNF341 | c.1176G>A p.Q392= (on ENST00000375200 / NM_001282935.1; = p.Q385= on NM_032819.4) | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs764166660, COSV61005821; called by muse, mutect2, varscan2
- ZNF804B | c.1419T>C p.Y473= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs751318170, COSV60816272; called by muse, mutect2, varscan2
- PDE4B | c.281+74306T>C | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58466425; called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222429 C>T | 5'Flank (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
